TCGA case TCGA-97-7554 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a9644274-13bb-4228-9b4f-14260ccc26eb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 83 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 83.0 years (30,327 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 111 days; Number of cycles: 4; Treatment dose: 1,400 mg; Prescribed dose: 350; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 111 days; Number of cycles: 4; Treatment dose: 3,268 mg; Prescribed dose: 817; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 264 days; Disease response: Tumor Free.
- Days to follow up: 775 days (2.1 years); Disease response: Tumor Free.
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.
- ECOG performance status: 0; Timepoint: Preoperative.

Molecular and laboratory tests
- KRAS substitution: Positive; Amino-acid change: G12V.

Other clinical attributes
- DLCO (% of predicted): 53; FEV1/FVC after bronchodilator (%): 75; FEV1/FVC before bronchodilator (%): 76; FEV1 after bronchodilator (% of reference): 75; FEV1 before bronchodilator (% of reference): 68.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1945; Tobacco smoking quit year: 1983.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-97-7554-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-97-7554-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 55; Percent normal cells: 5; Percent necrosis: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 5.
  Slide TCGA-97-7554-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent necrosis: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2.
- Sample TCGA-97-7554-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-97-7554-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Papillary Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Lower; KRAS mutation found: Yes; KRAS gene analysis indicator: Yes; KRAS mutation identified type: G12V; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Alimta.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 775 days; disease-specific survival: no event (censored), 775 days; disease-free interval: no event (censored), 775 days; progression-free interval: no event (censored), 775 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-97-7554-01A-11D-2035-01): tumor purity 0.29, ploidy 5.21, whole-genome doublings 2.
